Somatic mutation profile of tumor specimen TCGA-CC-5259-01A (aliquot TCGA-CC-5259-01A-31D-A20W-10) from TCGA case TCGA-CC-5259, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 60.1 years (21,946 days).
Specimen TCGA-CC-5259-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37e32067-eb40-493d-99a6-36e245a64a6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-5259-10A (Blood Derived Normal), aliquot TCGA-CC-5259-10A-01D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83a9cce5-05c5-4b3f-afa4-d0be9e2f274b

The open-access MAF lists 156 somatic variants for this specimen: 125 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 27, Nonsense Mutation 12, Frame Shift Del 5, Splice Region 3, Splice Site 3, Intron 2, RNA 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 146/331 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 115/146 reads (79%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ACAT2 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 53/209 reads (25%) | catalogued as COSV65454891; called by muse, mutect2, varscan2
- ACSM4 | c.801G>C p.W267C | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68068836, COSV68069144; called by muse, mutect2
- ADCY1 | c.1111T>A p.C371S | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.598); catalogued as COSV52037007; called by muse, mutect2, varscan2
- ADCY1 | c.1717T>A p.L573I | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52041423, COSV99812132; called by muse, mutect2, varscan2
- AHNAK | c.9078A>T p.K3026N | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57227613; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4189A>G p.I1397V | Missense Mutation (SNP) | VAF 118/189 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.083); catalogued as rs765885427, COSV51856834; called by muse, mutect2, varscan2
- ANKRD26 | c.3146A>G p.N1049S | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV65777964; called by muse, mutect2, varscan2
- ANO4 | c.639A>T p.L213F (on ENST00000392977 / NM_001286615.2; = p.L178F on NM_178826.4) | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.482); catalogued as COSV54610815; called by muse, mutect2, varscan2
- APOB | c.11393C>G p.T3798R | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51949911; called by muse, mutect2, varscan2
- ARIH2 | c.632G>C p.R211T | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.447); catalogued as COSV62706109, COSV62706128; called by muse, mutect2, varscan2
- ARMC3 | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1043241137, COSV53066551; called by muse, mutect2, varscan2
- ATP7A | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 85/227 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV58452551; called by muse, mutect2, varscan2
- BCL3 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 88/477 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51234969, COSV99378250; called by muse, mutect2, varscan2
- BCOR | c.4049A>T p.Y1350F (on ENST00000378444 / NM_001123385.2; = p.Y1316F on NM_017745.6) | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV60716614; called by muse, mutect2, varscan2
- BRSK1 | c.125A>T p.K42I | Missense Mutation (SNP) | VAF 83/484 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV55335195; called by muse, mutect2, varscan2
- CA8 | c.24A>T p.E8D | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV58774289; called by muse, mutect2, varscan2
- CARD11 | c.1748A>G p.H583R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV62756898; called by muse, mutect2
- CATIP | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 31/48 reads (65%) | catalogued as COSV56824185; called by muse, mutect2, varscan2
- CATSPERD | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs369818912; called by muse, mutect2, varscan2
- CBFA2T2 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60072866, COSV60075453; called by muse, mutect2, varscan2
- CCDC134 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 120/154 reads (78%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as COSV55388906; called by muse, mutect2, varscan2
- CCDC47 | c.1313G>T p.R438I | Missense Mutation (SNP) | VAF 72/114 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56724531; called by muse, mutect2, varscan2
- CNGA2 | c.1920G>T p.M640I | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61706030, COSV61706224; called by muse, mutect2
- COL9A3 | c.1580A>T p.E527V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV58983871, COSV58986925; called by muse, mutect2, varscan2
- COLGALT2 | c.882C>G p.I294M | Missense Mutation (SNP) | VAF 121/269 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV62300466; called by muse, mutect2, varscan2
- CP | c.755A>T p.D252V | Missense Mutation (SNP) | VAF 111/223 reads (50%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.935); catalogued as COSV52833295; called by muse, mutect2, varscan2
- CRAT | c.1475A>T p.K492M | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58878942; called by muse, mutect2, varscan2
- CRIM1 | c.990T>C p.N330= | Splice Region (SNP) | VAF 78/256 reads (30%) | catalogued as COSV54871325; called by muse, mutect2, varscan2
- CXCR4 | c.664A>T p.I222F | Missense Mutation (SNP) | VAF 81/121 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54016066; called by muse, mutect2, varscan2
- CYB561 | c.261C>A p.H87Q | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761669903, COSV62540019, COSV62540179; called by muse, mutect2, varscan2
- DLG1 | c.22A>T p.T8S | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV58389912; called by muse, mutect2, varscan2
- DMXL1 | c.1823T>A p.L608Q | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60719795; called by muse, mutect2, varscan2
- DOCK1 | c.928A>T p.R310W | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV54756826; called by muse, mutect2, varscan2
- DOT1L | c.1828G>T p.D610Y | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV67112876; called by muse, mutect2
- DRG1 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 13/279 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV58919776; called by muse, mutect2
- DUOX1 | c.532A>G p.I178V | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1451530875, COSV58485862; called by muse, mutect2, varscan2
- EFNA4 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.1); catalogued as COSV55129486; called by muse, mutect2, varscan2
- EGFL6 | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63635012; called by muse, mutect2, varscan2
- EGFLAM | c.386G>C p.R129P | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.662); catalogued as COSV59315046; called by muse, mutect2, varscan2
- EXO1 | c.1016A>G p.D339G | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1184553142, COSV62219417; called by muse, mutect2, varscan2
- FBN2 | c.1693C>A p.Q565K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.824); catalogued as COSV52541128; called by muse, mutect2, varscan2
- FBXO36 | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as COSV52271707; called by muse, mutect2, varscan2
- GRIP2 | c.1886C>A p.A629E (on ENST00000619221; = p.A532E on NM_001080423.4) | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as COSV56124279; called by muse, mutect2, varscan2
- HELB | c.836A>T p.Q279L | Missense Mutation (SNP) | VAF 94/145 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV56075845; called by muse, mutect2, varscan2
- HPD | c.457A>G p.I153V | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs748745589, COSV56643493; called by muse, mutect2, varscan2
- HSH2D | c.352A>G p.R118G | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53739504; called by muse, mutect2, varscan2
- HSPA6 | c.560T>A p.L187Q | Missense Mutation (SNP) | VAF 109/284 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59062382; called by muse, mutect2, varscan2
- IFNGR1 | c.1438A>T p.R480* | Nonsense Mutation (SNP) | VAF 83/151 reads (55%) | catalogued as COSV62992571; called by muse, mutect2, varscan2
- ITIH6 | c.3302T>A p.L1101Q | Missense Mutation (SNP) | VAF 75/155 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV54493860; called by muse, mutect2, varscan2
- KCNG1 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 99/226 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.03); catalogued as rs1009163679, COSV65370345; called by muse, mutect2, varscan2
- KCNQ5 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 92/180 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as rs767297128, COSV59679440; called by muse, mutect2, varscan2
- KCNS1 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.199); catalogued as COSV60260940; called by muse, mutect2, varscan2
- KCTD8 | c.1005T>A p.D335E | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63595173; called by muse, mutect2, varscan2
- KLHL4 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 146/324 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV64139911; called by muse, mutect2, varscan2
- KNDC1 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as rs541722509, COSV58845042; called by muse, mutect2, varscan2
- KRT34 | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 82/115 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV67450578; called by muse, mutect2, varscan2
- KRT38 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 108/141 reads (77%) | SIFT tolerated (0.24); PolyPhen benign (0.117); catalogued as COSV55847383; called by muse, mutect2, varscan2
- KRTAP4-2 | c.226T>A p.C76S | Missense Mutation (SNP) | VAF 64/81 reads (79%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV66659090; called by muse, mutect2, varscan2
- MAGEB18 | c.754A>T p.K252* | Nonsense Mutation (SNP) | VAF 74/232 reads (32%) | catalogued as COSV57464909; called by muse, mutect2, varscan2
- MAGEC3 | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 128/328 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1278417044, COSV68924241; called by muse, mutect2
- MAK | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 52/140 reads (37%) | catalogued as COSV57567400; called by muse, mutect2, varscan2
- MAMDC4 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as COSV56034725; called by muse, mutect2, varscan2
- MED18 | c.22A>G p.M8V | Missense Mutation (SNP) | VAF 103/125 reads (82%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65790966; called by muse, mutect2, varscan2
- MSANTD1 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.24); catalogued as COSV70873330; called by muse, varscan2
- MYO10 | c.1675G>T p.G559C | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72563405; called by muse, mutect2, varscan2
- MYO5A | c.4340A>T p.Q1447L | Missense Mutation (SNP) | VAF 95/143 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62563986; called by muse, mutect2, varscan2
- MYRF | c.2314C>G p.L772V (on ENST00000278836 / NM_001127392.3; = p.L763V on NM_013279.4) | Missense Mutation (SNP) | VAF 120/249 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV53893384; called by muse, mutect2, varscan2
- NCAM1 | c.820A>G p.I274V | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.076); catalogued as rs782790715, COSV57523539; called by muse, mutect2, varscan2
- NET1 | c.493A>G p.K165E (on ENST00000355029 / NM_001047160.3; = p.K111E on NM_005863.5) | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as COSV61792558; called by muse, mutect2
- NSDHL | c.193A>G p.N65D | Missense Mutation (SNP) | VAF 99/215 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.725); catalogued as COSV64745041; called by muse, mutect2, varscan2
- OTOGL | c.4806G>C p.K1602N (on ENST00000547103; = p.K1593N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.663); catalogued as COSV54022586; called by muse, mutect2, varscan2
- OXR1 | c.1255G>T p.E419* (on ENST00000442977 / NM_001198532.1; = p.E418* on NM_018002.3) | Nonsense Mutation (SNP) | VAF 18/166 reads (11%) | catalogued as COSV56335438; called by muse, mutect2, varscan2
- PCDH15 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 37/143 reads (26%) | catalogued as COSV57290951, COSV57381192; called by muse, mutect2, varscan2
- PCDH9 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 58/67 reads (87%) | catalogued as COSV100119593, COSV60583607; called by muse, mutect2, varscan2
- PEPD | c.322A>T p.M108L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV54895375; called by muse, mutect2, varscan2
- PGLYRP4 | c.66C>A p.N22K | Missense Mutation (SNP) | VAF 130/281 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.086); catalogued as COSV62835596, COSV62836233; called by muse, mutect2, varscan2
- PPP1R3F | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.981); catalogued as COSV50020128; called by muse, mutect2, varscan2
- PREX2 | c.4399G>T p.A1467S | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV55750117, COSV55796091; called by muse, mutect2
- PRKDC | c.3220A>T p.K1074* | Nonsense Mutation (SNP) | VAF 34/70 reads (49%) | catalogued as COSV58061693; called by muse, mutect2, varscan2
- PRSS37 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV63340055; called by muse, mutect2, varscan2
- PSMD1 | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV58082881; called by muse, mutect2, varscan2
- PXDNL | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs776683885, COSV62494746; called by muse, mutect2, varscan2
- RAI2 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs140631545, COSV58963272; called by muse, mutect2
- RAP1GAP2 | c.1976G>A p.S659N | Missense Mutation (SNP) | VAF 90/110 reads (82%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV54586759; called by muse, mutect2, varscan2
- RB1CC1 | c.4500-2A>C p.X1500_splice | Splice Site (SNP) | VAF 20/67 reads (30%) | catalogued as COSV50270551; called by muse, mutect2, varscan2
- RGS18 | c.140G>C p.R47T | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1260393099, COSV104427464, COSV66509805; called by muse, mutect2
- RO60 | c.1082T>G p.F361C | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66474833; called by muse, mutect2, varscan2
- RPS6KA6 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53125835; called by muse, mutect2, varscan2
- SAGE1 | c.1035C>A p.H345Q | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV61017110; called by muse, mutect2, varscan2
- SAMD9 | c.2936G>T p.C979F | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV66077291; called by muse, mutect2, varscan2
- SCAI | c.1480A>T p.S494C (on ENST00000336505 / NM_001144877.3; = p.S517C on NM_173690.5) | Missense Mutation (SNP) | VAF 86/180 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57176241; called by muse, mutect2, varscan2
- SCN11A | c.5335T>A p.S1779T | Missense Mutation (SNP) | VAF 95/182 reads (52%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.021); catalogued as COSV56576946; called by muse, mutect2, varscan2
- SLC25A12 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 45/71 reads (63%) | catalogued as COSV55536694; called by muse, mutect2, varscan2
- SLC44A5 | c.1571C>A p.A524E | Missense Mutation (SNP) | VAF 59/87 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63773380; called by muse, mutect2, varscan2
- SPTA1 | c.6205C>A p.P2069T | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV63758267; called by muse, mutect2
- SPTBN2 | c.4130G>A p.R1377H | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs767535278, COSV59460246; called by muse, mutect2, varscan2
- STAB2 | c.6839A>G p.N2280S | Missense Mutation (SNP) | VAF 83/150 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV66345773; called by muse, mutect2, varscan2
- STAT6 | c.1639G>A p.V547I | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.387); catalogued as rs766506451, COSV55667747; called by muse, mutect2, varscan2
- SYNGAP1 | c.2837G>C p.G946A | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT tolerated (0.74); PolyPhen benign (0.209); catalogued as COSV53386002; called by muse, mutect2, varscan2
- TAF1 | c.3460G>A p.E1154K (on ENST00000373790 / NM_138923.4; = p.E1175K on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 205/537 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.351); catalogued as COSV52123457; called by muse, mutect2, varscan2
- TBXT | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs756318370, COSV51616134; called by muse, mutect2, varscan2
- TECRL | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.378); catalogued as COSV67090073; called by muse, mutect2, varscan2
- TENT4B | c.1800A>G p.V600= (on ENST00000561678 / NM_001365323.2; = p.V585= on NM_001040284.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 40/108 reads (37%) | catalogued as rs759353281, COSV62549163; called by muse, varscan2
- TINAG | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 25/42 reads (60%) | catalogued as COSV52514075; called by muse, mutect2, varscan2
- TRAF7 | c.1688A>T p.Y563F | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58214142, COSV58216392; called by muse, mutect2, varscan2
- TRPS1 | c.2197A>T p.I733L (on ENST00000220888 / NM_001330599.2; = p.I746L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/428 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55258735; called by muse, mutect2, varscan2
- UBC | c.178A>C p.N60H | Missense Mutation (SNP) | VAF 10/271 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100299163; called by muse, mutect2
- UBE2D3 | c.304+2T>G p.X102_splice | Splice Site (SNP) | VAF 167/221 reads (76%) | catalogued as COSV57663465, COSV57664132; called by muse, mutect2, varscan2
- UNC79 | c.3926A>T p.K1309M (on ENST00000393151 / NM_001346218.2; = p.K1132M on NM_020818.5) | Missense Mutation (SNP) | VAF 77/95 reads (81%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV56407020; called by muse, mutect2, varscan2
- VEGFC | c.1253T>G p.M418R | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV54605231; called by muse, varscan2
- WDR64 | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764415019, COSV63799857; called by muse, mutect2, varscan2
- ZNF135 | c.598G>C p.D200H (on ENST00000313434 / NM_001289401.2; = p.D212H on NM_003436.4) | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.096); catalogued as COSV57885359; called by muse, mutect2, varscan2
- ZNF224 | c.1001A>T p.H334L | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61243327; called by muse, mutect2, varscan2
- ZNF354C | c.314C>A p.T105K | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV59609637; called by muse, mutect2
- ZNF567 | c.1282A>T p.K428* (on ENST00000536254 / NM_001322913.1; = p.K397* on NM_152603.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV62446361; called by muse, mutect2, varscan2
- ZNF91 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV100322612, COSV56091657; called by muse, mutect2, varscan2
- ARMCX3 | c.728del p.N243Ifs*22 | Frame Shift Del (DEL) | VAF 75/181 reads (41%) | called by mutect2, pindel, varscan2
- IGLV7-46 | c.340A>T p.S114C | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- PCF11 | c.2399del p.G800Efs*5 | Frame Shift Del (DEL) | VAF 15/116 reads (13%) | called by mutect2, pindel, varscan2
- PHLDB2 | c.184_185delinsG p.L62Afs*24 | Frame Shift Del (DEL) | VAF 59/152 reads (39%) | called by pindel, varscan2*
- PLXDC2 | c.794del p.L265Wfs*5 | Frame Shift Del (DEL) | VAF 38/107 reads (36%) | called by mutect2, pindel, varscan2
- PTH2R | c.1036del p.E346Rfs*25 | Frame Shift Del (DEL) | VAF 135/268 reads (50%) | called by mutect2, pindel, varscan2
- SPATA5 | c.2206_2213+4del p.X736_splice | Splice Site (DEL) | VAF 55/146 reads (38%) | called by mutect2, pindel, varscan2
- ARHGEF25 | c.703C>T p.L235= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV54090007; called by muse, mutect2
- CACTIN | c.1992C>T p.D664= | Silent (SNP) | VAF 423/574 reads (74%) | catalogued as rs754086361, COSV50272495; called by muse, mutect2, varscan2
- CD5L | c.498C>T p.G166= | Silent (SNP) | VAF 53/118 reads (45%) | catalogued as COSV63822956; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.858C>T p.H286= | Silent (SNP) | VAF 101/219 reads (46%) | catalogued as rs531845693, COSV55829184; called by muse, mutect2, varscan2
- DMXL2 | c.1875A>T p.A625= | Silent (SNP) | VAF 67/90 reads (74%) | catalogued as COSV51854549; called by muse, mutect2, varscan2
- DNAH3 | c.4290A>T p.P1430= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV54546938; called by muse, mutect2, varscan2
- FABP9 | c.117G>T p.P39= | Silent (SNP) | VAF 55/233 reads (24%) | catalogued as COSV66911781; called by muse, mutect2, varscan2
- FAM217B | c.117T>A p.A39= | Silent (SNP) | VAF 59/177 reads (33%) | catalogued as COSV62565022; called by muse, mutect2, varscan2
- FHOD3 | c.1050C>T p.G350= | Silent (SNP) | VAF 80/176 reads (45%) | catalogued as rs531088835, COSV99943310; called by muse, mutect2, varscan2
- GPX6 | c.147C>T p.N49= | Silent (SNP) | VAF 55/117 reads (47%) | catalogued as rs767523979, COSV62657330, COSV62659016; called by muse, mutect2, varscan2
- GRM3 | c.1113C>T p.R371= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as rs1432324457, COSV64478575; called by muse, mutect2, varscan2
- HIVEP3 | c.1755G>C p.R585= | Silent (SNP) | VAF 62/83 reads (75%) | catalogued as COSV56022345; called by muse, mutect2, varscan2
- IDO2 | c.1206C>A p.I402= (on ENST00000389060; = p.I415= on NM_194294.2) | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs1270954691, COSV58428663; called by muse, mutect2, varscan2
- MUC16 | c.21666T>A p.T7222= | Silent (SNP) | VAF 99/144 reads (69%) | catalogued as COSV67489095; called by muse, mutect2, varscan2
- OR9G1 | c.231C>A p.T77= | Silent (SNP) | VAF 54/253 reads (21%) | catalogued as COSV56453734; called by muse, mutect2, varscan2
- PHF5A | c.204T>C p.D68= | Silent (SNP) | VAF 92/130 reads (71%) | catalogued as COSV53440238; called by muse, mutect2, varscan2
- PIP5K1B | c.237A>T p.P79= | Silent (SNP) | VAF 51/117 reads (44%) | catalogued as COSV55256496; called by muse, mutect2, varscan2
- PIWIL2 | c.972T>C p.N324= | Silent (SNP) | VAF 96/175 reads (55%) | catalogued as COSV63253747; called by muse, mutect2, varscan2
- PTCHD4 | c.66G>C p.V22= | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as COSV59795427; called by muse, mutect2, varscan2
- RELN | c.1836C>A p.I612= | Silent (SNP) | VAF 39/69 reads (57%) | catalogued as COSV59030094; called by muse, mutect2, varscan2
- RIMBP3 | c.2754C>G p.L918= | Silent (SNP) | VAF 36/614 reads (6%) | called by muse, mutect2
- SLC44A5 | c.1572A>C p.A524= | Silent (SNP) | VAF 61/89 reads (69%) | catalogued as COSV63773371; called by muse, mutect2, varscan2
- TBC1D8 | c.393C>T p.A131= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs753489134, COSV65216050; called by muse, mutect2, varscan2
- TCF4 | c.414C>T p.T138= | Silent (SNP) | VAF 91/183 reads (50%) | catalogued as COSV61905110; called by muse, mutect2, varscan2
- USH2A | c.7476G>A p.S2492= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs777803742, COSV56331334; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZMYM3 | c.1989G>A p.L663= | Silent (SNP) | VAF 61/189 reads (32%) | catalogued as rs200745411, COSV58740412; called by muse, mutect2, varscan2
- ZNF260 | c.393A>T p.T131= | Silent (SNP) | VAF 37/194 reads (19%) | catalogued as COSV72951286; called by muse, mutect2, varscan2
- BLVRB | c.-1G>T | 5'UTR (SNP) | VAF 160/232 reads (69%) | catalogued as COSV99647869, COSV99648075; called by muse, mutect2, varscan2
- DCHS2 | n.2798T>A | RNA (SNP) | VAF 46/104 reads (44%) | catalogued as COSV59738041; called by muse, mutect2, varscan2
- FBXW7 | c.502-2562T>A | Intron (SNP) | VAF 15/53 reads (28%) | catalogued as COSV55950096; called by muse, mutect2, varscan2
- FMN1 | c.2044-2015T>A | Intron (SNP) | VAF 60/83 reads (72%) | catalogued as COSV57931818; called by muse, mutect2, varscan2
